Gene-level copy-number profile of tumor specimen TCGA-25-1634-01A from TCGA case TCGA-25-1634, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 76.0 years (27,749 days).
Specimen TCGA-25-1634-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.cee2a595-164b-4263-9f5c-fb80463b0675.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-25-1634-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/30bc6621-3596-407b-9f42-5398174b5aa9

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,522; copy number 2: 6,713; copy number 3: 17,608; copy number 4: 13,586; copy number 5: 6,168; copy number 6: 9,452; copy number 7: 2,827; copy number 8: 359; copy number 9: 43; copy number 10: 38; copy number 11: 51; copy number 12: 264; copy number 13: 74; copy number 14: 1; copy number 15: 24; copy number 16: 37; copy number 17: 15; copy number 19: 15; copy number 22: 13; copy number 31: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-25-1634-01): tumor purity 0.85, ploidy 4.05, whole-genome doublings 2 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,770 genes in 39 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:38,129,464–41,043,890, 97 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr1:105,587,575–109,238,182, 58 genes, copy number 7: LINC01676, SEPTIN2P1, AL512844.2, AL512844.1, LINC01677, AL355306.2, AL355306.1, AL499605.1, AL596327.1, MTATP6P14, MTCO1P14, LINC01661, PRMT6, NTNG1, NDUFA4P1, VAV3, MIR7852, VAV3-AS1, LINC02785, SLC25A24, AL359258.2, AL359258.3, NBPF4, AL359258.1, SLC25A24P1, NBPF5P, SLC25A24P2, AL390038.1, NBPF6, AL392088.2, ST13P21, AL392088.1, FAM102B, HENMT1, AL160171.1, PRPF38B, FNDC7, AL591719.2, STXBP3, AL591719.1, AKNAD1, SPATA42, GPSM2, CLCC1, WDR47, BX679664.2, BX679664.3, BX679664.1, RANP5, TAF13, AL356488.3, TMEM167B, SCARNA2, AL356488.2, AL356488.1, C1orf194, ELAPOR1, SARS1.
- chr1:163,422,405–164,899,296, 15 genes, copy number 8: AL603841.1, RNA5SP62, RNA5SP63, AL355862.1, U3, NMNAT1P2, RNU5F-6P, HMGB3P6, PBX1, RNU6-171P, AL391001.1, Metazoa_SRP, PBX1-AS1, AL357568.1, Y_RNA.
- chr1:184,385,753–197,935,478, 149 genes, copy number 7 (broad region; genes not listed).
- chr1:236,795,292–248,919,946, 279 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr2:4,514,204–5,812,670, 12 genes, copy number 7: NPM1P48, LINC01249, AC092169.1, RNU6-649P, AC073143.1, AC107057.1, LINC01248, AC108025.1, SOX11, AC010729.2, AC010729.1, LINC01810.
- chr2:21,094,101–22,861,884, 17 genes, copy number 7: AC010872.2, TDRD15, AC067959.1, AC018742.1, AC011752.1, NUTF2P8, AC009411.2, AC009411.1, LINC01822, RN7SL117P, AC096570.1, AC068044.1, AC099799.1, RNA5SP87, LINC01830, LINC01884, RN7SKP27.
- chr2:48,809,340–49,419,013, 1 gene, copy number 7 (within-gene range 6–7): AC009975.1.
- chr2:48,962,157–52,702,615, 29 genes, copy number 7 (within-gene range 6–7): FSHR, MIR548BA, AC009975.2, RNU6-439P, AC009971.1, RPL7P13, SNORA75, NRXN1, AC068725.1, MTCO1P42, AC009234.1, MIR8485, AC007560.1, AC007682.1, AC007402.1, AC007402.2, KNOP1P3, CRYGGP, AC097463.1, CCDC12P1, AC079304.1, ZNF863P, Y_RNA, LINC01867, GGCTP3, AC139712.1, CRTC1P1, FTH1P6, MIR4431.
- chr2:66,235,377–67,684,077, 21 genes, copy number 7: AC118345.1, AC092669.1, MIR4778, LINC01873, MEIS1-AS3, MEIS1, MEIS1-AS2, LINC01798, LINC01797, DNMT3AP1, AC009474.1, LINC01799, LINC01628, AC007403.1, LINC01828, LINC01829, AC023115.1, ETAA1, LINC02831, AC007422.1, AC010987.1.
- chr2:75,710,782–83,657,842, 70 genes, copy number 8 (broad region; genes not listed).
- chr2:114,442,299–115,845,780, 1 gene, copy number 7 (within-gene range 6–7): DPP10.
- chr2:115,079,354–117,181,562, 13 genes, copy number 7: AC093610.1, DPP10-AS1, RPSAP23, AC016721.1, AC104408.1, AC062016.1, MTCYBP39, AC062016.2, MTND1P28, MTND2P21, MTCO1P43, RNU7-190P, AC092170.1.
- chr2:139,323,921–142,131,016, 20 genes, copy number 7 (within-gene range 6–7): AC013265.1, AC062021.1, AC016710.1, SNORA72, MRPS18BP2, RPL9P13, AC078851.1, RN7SL283P, LINC01853, MTCO1P44, MTND2P19, MTND1P27, LRP1B, AC092156.1, MIR7157, COPRSP1, LRRC57P1, Y_RNA, RNU6-904P, RPS16P3.
- chr2:171,317,405–221,650,218, 876 genes, copy number 7 (broad region; genes not listed).
- chr2:222,671,658–224,402,107, 24 genes, copy number 7 (within-gene range 5–7): MOGAT1, RRAS2P2, AC104772.1, RPL31P17, ACSL3, ATG12P2, ACSL3-AS1, AC013476.1, KCNE4, RN7SL807P, HIGD1AP4, AC013448.1, AC013448.2, SCG2, MLXP1, AP1S3, AC093884.1, WDFY1, MRPL44, AC073641.1, SERPINE2, USP21P1, AC008072.1, FAM124B.
- chr2:225,992,981–242,160,153, 371 genes, copy number 7 (broad region; genes not listed).
- chr3:89,107,621–97,752,460, 39 genes, copy number 7 (within-gene range 6–7): EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19, ABBA01000933.1, ABBA01000935.2, RNU6-488P, PROS1, Y_RNA, RNU6-511P, ARL13B, HMGN1P7, STX19, DHFR2, NSUN3, RBBP4P2, ARMC10P1, AC140059.1, WDR82P1, LINC00879, RPS18P6, MTHFD2P1, AC106719.1, AC107304.1, HNRNPKP4, MIR8060, AC107015.1, RNU6-1094P, MTRNR2L12, RPL18AP8, RCC2P5, CDV3P1, AC109782.1, EPHA6, AC117470.1.
- chr3:162,486,541–169,038,416, 57 genes, copy number 7: TOMM22P6, AC128716.1, AC128685.1, LINC01192, RPS6P4, AC079910.1, RNU7-82P, AC084017.1, MIR1263, LINC01323, LINC01324, SI, Y_RNA, LINC02023, SLITRK3, LINC01322, BCHE, MTND4P17, MTND4LP10, MTND3P7, MTCO3P38, MCUR1P2, AC104629.1, LINC01326, AC072046.2, RN7SKP298, PSAT1P4, AC072046.1, CBX1P5, AC069439.2, AC069439.1, PPIAP74, ZBBX, LINC01327, SERPINI2, WDR49, PDCD10, HMGN1P8, SERPINI1, AC079822.1, LRRC77P, AC026353.1, MEMO1P3, AC128713.1, HMGN2P26, GOLIM4, AC069243.1, EGFEM1P, AC124893.1, RNU2-20P, MIR551B, RPSAP33, RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997.
- chr3:172,889,357–174,378,005, 8 genes, copy number 7 (within-gene range 6–7): SPATA16, AC068759.1, NLGN1, AC092967.1, NLGN1-AS1, RN7SKP234, ANAPC15P2, AC069218.1.
- chr3:174,631,823–174,632,064, 1 gene, copy number 7: RN7SKP40.
- chr5:2,712,591–4,970,425, 24 genes, copy number 8: LSINCT5, AC091891.1, IRX2, C5orf38, AC116359.1, AC094105.1, AC094105.2, LINC01377, LINC01019, LINC02162, LINC01017, IRX1, AC016595.1, AC025773.1, AC025187.1, LINC02063, AC106799.3, AC106799.2, AC106799.1, AC010634.1, LINC02114, AC026719.1, AC026415.1, AC010451.3.
- chr5:17,684,584–45,895,970, 370 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr5:166,905,222–168,264,157, 11 genes, copy number 7 (within-gene range 5–7): LINC01947, AC091819.2, AC091819.1, TENM2, AC091820.2, AC091820.1, AC008601.1, AC008708.2, AC008708.1, AC008464.1, AC008705.2.
- chr6:8,158,162–8,760,447, 1 gene, copy number 7 (within-gene range 6–7): AL355499.2.
- chr6:8,411,435–10,211,608, 5 genes, copy number 7 (within-gene range 6–7): SLC35B3, HULC, AL161437.1, AL137220.1, OFCC1.
- chr6:17,281,361–23,857,646, 75 genes, copy number 7 (broad region; genes not listed).
- chr6:44,727,921–57,961,501, 200 genes, copy number 7 (broad region; genes not listed).
- chr6:57,967,687–58,073,134, 2 genes, copy number 7: GAPDHP15, AL390237.1.
- chr6:60,281,444–65,707,226, 37 genes, copy number 7–16 (within-gene range 3–16): AC244258.1, GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3, AL356131.1, MTRNR2L9, KHDRBS2-OT1, KHDRBS2, AL355347.1, DHFRP5, AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3, EYS, AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2, AL355357.1.
- chr6:66,710,242–66,728,904, 2 genes, copy number 15: AL450336.1, RNU7-66P.
- chr6:101,181,257–102,070,083, 1 gene, copy number 14 (within-gene range 5–31): GRIK2.
- chr6:102,078,872–107,115,515, 52 genes, copy number 17–31: AP002530.1, AL357139.2, AL357139.1, Z98755.1, AL591387.1, AL590608.1, R3HDM2P2, NPM1P10, AL357522.1, AL356967.1, HACE1, RNU6-897P, AL357315.1, AL357315.2, LIN28B-AS1, LIN28B, RNU6-1106P, BVES, BVES-AS1, POPDC3, PREP, AL133406.2, AL133406.1, RPL35P3, AL096794.1, LINC02836, Z97206.1, AL591518.1, RN7SKP211, PRDM1, ATG5, AL022067.1, U4, RN7SL47P, RNU6-344P, AL356859.1, CRYBG1, Y_RNA, RNA5SP211, AL109920.1, Y_RNA, RTN4IP1, RNU6-527P, QRSL1, RPL21P65, LINC02526, LINC02532, RNU6-117P, MIR587, CD24, MTRES1, BEND3.
- chr6:167,826,922–170,738,536, 67 genes, copy number 8 (within-gene range 4–8) (broad region; genes not listed).
- chr10:8,161,260–10,795,047, 26 genes, copy number 7: PRPF38AP1, LINC00708, AL390835.1, AC025946.1, AC025946.2, KRT8P37, CHCHD3P1, RNA5SP299, AL355333.1, LINC02676, AC044784.1, LINC00709, AL138773.1, HSP90AB7P, LINC02663, LINC02670, ELOCP3, Y_RNA, CUX2P1, AL354916.1, AL583859.1, CELF2-DT, AL583859.2, AL583859.3, AL136452.1, SFTA1P.
- chr10:36,089,086–38,719,229, 56 genes, copy number 7: AL355300.1, MTND5P17, MTND4P18, AL590730.1, AL590730.2, NAMPTP1, Y_RNA, AL390061.1, MKNK2P1, ARL6IP1P2, ANKRD30A, RNU6-811P, AL157387.1, LINC00993, RN7SL314P, Y_RNA, TMEM161BP1, VN1R53P, TACC1P1, MTND1P18, MTRNR2L7, AL132657.1, ZNF248, AL132657.2, ZNF33BP1, TLK2P2, AL135791.1, ZNF37CP, ZNF33CP, ZNF25, ZNF25-DT, Y_RNA, ZNF33A, RNU6-795P, AL161931.1, EIF3LP3, FXYD6P2, ZNF37A, AL117339.4, AL117339.3, AL117339.1, CCNYL4, AL133217.1, AL117339.2, HSD17B7P2, SEPTIN7P9, AL133216.2, RNU6-1118P, CICP9, AL133216.1, ABCD1P2, AL133173.2, PABPC1P12, SLC9B1P3, ACTR3BP5, CHEK2P5.
- chr12:166,856–5,946,232, 134 genes, copy number 8–16 (within-gene range 6–16) (broad region; genes not listed).
- chr12:6,438,498–24,562,544, 483 genes, copy number 7–13 (within-gene range 6–13) (broad region; genes not listed).
- chr20:87,250–2,177,038, 66 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 101. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
